Gene-level copy-number profile of tumor specimen TCGA-PG-A914-01A from TCGA case TCGA-PG-A914, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 73.9 years (26,992 days).
Specimen TCGA-PG-A914-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.3232b3ee-fea0-4aec-93f7-afa71e0b32ed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PG-A914-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/63b4fc14-5e1e-49c6-a239-24be48c4ce6f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 969; copy number 2: 12,107; copy number 3: 20,161; copy number 4: 17,878; copy number 5: 4,041; copy number 6: 2,127; copy number 7: 1,104; copy number 8: 757; copy number 9: 124; copy number 10: 199; copy number 11: 59; copy number 12: 29; copy number 13: 47; copy number 14: 15; copy number 15: 5; copy number 19: 50; copy number 20: 36; copy number 21: 13; copy number 27: 36; copy number 29: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PG-A914-01A-11D-A37M-01): tumor purity 0.8, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,511 genes in 62 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,824,088–150,476,566, 173 genes, copy number 10–29 (within-gene range 4–29) (broad region; genes not listed).
- chr1:153,658,703–153,923,360, 16 genes, copy number 8 (within-gene range 4–8): SNAPIN, ILF2, NPR1, MIR8083, RN7SL372P, GEMIN2P1, Y_RNA, INTS3, AL513523.4, AL513523.3, SLC27A3, Y_RNA, GATAD2B, AL513523.2, AL513523.1, AL831737.1.
- chr1:204,368,431–204,707,430, 13 genes, copy number 7: LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75.
- chr2:96,497,646–99,401,326, 81 genes, copy number 7 (broad region; genes not listed).
- chr2:180,473,137–185,957,063, 60 genes, copy number 7–11: AC012669.1, AC009478.1, SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1, LINC01934, MIR4437, AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113, PDE1A, AC012500.1, RN7SL267P, DNAJC10, RPL31P15, Y_RNA, FRZB, RNU6-1122P, NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35, AC021851.1, AC021851.2, LIN28AP1, CACYBPP2, AC093639.3, AC093639.1, AC093639.2, AC096555.1, AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33, AC009315.1, ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2, AC097500.1, RPL21P32.
- chr2:188,974,373–191,020,960, 41 genes, copy number 7 (within-gene range 4–7): COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1.
- chr3:45,555,394–45,916,042, 11 genes, copy number 7 (within-gene range 4–7): LIMD1, LIMD1-AS1, SACM1L, RN7SL145P, AC098476.1, SLC6A20, LZTFL1, AC099782.1, SDHDP4, CCR9, Y_RNA.
- chr6:18,223,860–18,468,870, 7 genes, copy number 8: DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B.
- chr6:97,283,303–98,400,869, 5 genes, copy number 15 (within-gene range 3–15): AL589740.1, AL080316.1, MIR2113, EIF4EBP2P3, AL590727.1.
- chr6:120,686,621–122,726,373, 27 genes, copy number 8 (within-gene range 3–8): RNA5SP215, COX6A1P3, AL357513.1, TBC1D32, RNU6-1286P, Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P, HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2.
- chr7:10,973,336–32,762,924, 350 genes, copy number 8–14 (broad region; genes not listed).
- chr7:36,109,024–36,390,125, 9 genes, copy number 9 (within-gene range 5–9): MARK2P13, AC078841.1, EEPD1, AC007327.1, AC007327.2, AC006960.1, AC006960.3, KIAA0895, Y_RNA.
- chr7:37,683,843–42,264,100, 72 genes, copy number 8–13 (within-gene range 5–13) (broad region; genes not listed).
- chr7:42,794,906–43,113,931, 10 genes, copy number 10: TCP1P1, AC010132.1, AC010132.4, C7orf25, AC010132.3, PSMA2, AC010132.2, MRPL32, AC005537.1, Y_RNA.
- chr7:44,379,119–48,108,736, 75 genes, copy number 8 (broad region; genes not listed).
- chr7:54,330,670–55,572,988, 20 genes, copy number 8: LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.
- chr7:138,797,952–139,777,998, 23 genes, copy number 8 (within-gene range 5–8): TMEM213, KIAA1549, RNU6-1272P, ZC3HAV1L, ZC3HAV1, AC018644.1, TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2, RNU6-206P, FMC1, LUC7L2, FMC1-LUC7L2, AC083880.1, RNU6-911P, KLRG2, AC005531.1, CLEC2L, ERHP1, HIPK2.
- chr8:39,522,976–42,139,752, 49 genes, copy number 21–27 (within-gene range 4–27): AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4.
- chr8:97,273,488–98,036,724, 12 genes, copy number 7 (within-gene range 5–7): TSPYL5, SNORD3H, AP002982.1, AP002982.2, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2.
- chr8:101,034,868–137,425,021, 458 genes, copy number 7–8 (broad region; genes not listed).
- chr8:141,252,286–141,432,454, 9 genes, copy number 8: AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3.
- chr8:142,611,049–144,950,888, 153 genes, copy number 7 (broad region; genes not listed).
- chr11:73,157,946–73,397,474, 10 genes, copy number 7: AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4.
- chr12:5,948,877–7,071,032, 75 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr12:98,485,544–98,735,433, 8 genes, copy number 8 (within-gene range 4–8): LINC02453, TMPO-AS1, TMPO, PPIAP8, SLC25A3, SNORA53, IKBIP, APAF1.
- chr13:113,491,021–114,337,626, 29 genes, copy number 7 (within-gene range 5–7): TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1, CFAP97D2, AL160396.1, CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr17:52,985,513–54,771,277, 15 genes, copy number 9: LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14.
- chr17:57,771,946–59,215,247, 66 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr17:67,637,774–68,257,712, 28 genes, copy number 8 (within-gene range 3–8): AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1.
- chr18:21,242,242–23,437,961, 48 genes, copy number 8 (within-gene range 3–8): GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1.
- chr19:14,950,034–16,690,023, 102 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr19:18,058,995–18,323,112, 17 genes, copy number 9 (within-gene range 5–9): IL12RB1, MAST3, AC007192.2, AC007192.1, PIK3R2, IFI30, MPV17L2, RAB3A, AC005759.1, AC008397.2, PDE4C, AC008397.1, IQCN, JUND, MIR3188, RPL39P38, LSM4.
- chr20:87,250–397,559, 14 genes, copy number 10: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3.
- chr20:603,797–6,780,246, 181 genes, copy number 8 (broad region; genes not listed).
- chr20:34,234,840–34,347,785, 5 genes, copy number 8 (within-gene range 4–8): AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1.
- chr20:41,136,960–41,383,107, 10 genes, copy number 9 (within-gene range 6–9): PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1.
- chr22:30,182,818–32,498,829, 118 genes, copy number 7–20 (broad region; genes not listed).
- chr22:35,066,136–35,729,483, 23 genes, copy number 8 (within-gene range 5–8): ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5.
- chr22:37,180,166–38,041,915, 42 genes, copy number 9 (within-gene range 6–9): C1QTNF6, SSTR3, Z82188.1, RAC2, CYTH4, ELFN2, Z94160.1, ELFN2, Z94160.2, MFNG, CARD10, AL022315.1, CDC42EP1, LGALS2, Metazoa_SRP, GGA1, SH3BP1, Z83844.2, PDXP-DT, PDXP, RN7SL385P, LGALS1, NOL12, Z83844.1, TRIOBP, H1-0, GCAT, GALR3, ANKRD54, MIR658, MIR659, EIF3L, AL022311.1, RNU6-900P, MICALL1, AL031587.5, C22orf23, AL031587.3, POLR2F, MIR6820, SOX10, MIR4534.
- chr22:39,223,359–39,320,389, 7 genes, copy number 10 (within-gene range 6–10): PDGFB, AL031590.1, AL022326.1, RPL3, SNORD83B, SNORD83A, SNORD43.

Autosomal genes at a single copy (total copy number 1): 954. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
